Gene-level copy-number profile of tumor specimen AP-94ED-LQ from APOLLO case AP-94ED, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3.
Specimen AP-94ED-LQ: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 82563fa0-f395-4de8-8481-47fc18910c92.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-94ED-WK (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/88621028-5d0f-4198-a05c-e8dbb0081647

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 9,259; copy number 2: 23,682; copy number 3: 18,986; copy number 4: 6,025; copy number 5: 571; copy number 6: 185; copy number 7: 41; copy number 9: 6; copy number 11: 24; copy number 16: 1; copy number 17: 16.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:132,147,591–132,257,969, 4 genes (within-gene range 0–1): ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B.
- chr6:61,574,328–61,574,402, 1 gene: MTRNR2L9.
- chr9:40,481,558–40,883,763, 10 genes: AQP7P5, FP885919.1, AMYH02020865.1, BMS1P14, FP325318.1, IGKV1OR9-2, AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr10:130,213,488–131,311,721, 6 genes: LINC02646, AL157712.1, Y_RNA, MIR378C, TCERG1L, TCERG1L-AS1.
- chr10:132,783,179–133,778,699, 60 genes (within-gene range 0–1): NKX6-2, CFAP46, LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15, RPL23AP60, BX322534.1.
- chr11:48,880,111–48,961,810, 6 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2.
- chr15:19,878,555–20,359,166, 23 genes: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1, BCAR1P1, RN7SL584P, AC087386.1, AC087386.2, BMS1P15, RHPN2P1, CHEK2P2, AC026495.1.
- chr21:17,210,469–17,450,104, 4 genes: NEK4P1, AP000457.1, RNU6-113P, LINC01549.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 844 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:37,562,486–37,646,698, 1 gene, copy number 5 (within-gene range 3–5): AC006369.1.
- chr3:61,561,569–65,053,439, 44 genes, copy number 5: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994, PRICKLE2, PRICKLE2-AS1, PRICKLE2-AS2, PRDX3P4, PRICKLE2-AS3, PRICKLE2-DT, RNU6-739P, ADAMTS9, ADAMTS9-AS1, ADAMTS9-AS2.
- chr4:101,023,409–101,348,883, 4 genes, copy number 5: PPP3CA, MIR8066, MIR1255A, FLJ20021.
- chr4:102,500,841–102,868,896, 12 genes, copy number 5: AF213884.3, NFKB1, MANBA, AF213884.1, LRRC37A15P, KRT8P46, AC018797.1, AC018797.2, UBE2D3, AC018797.3, UBE2D3-AS1, RNU7-151P.
- chr5:1,456,480–31,555,053, 393 genes, copy number 5–6 (broad region; genes not listed).
- chr5:32,103,445–34,244,796, 40 genes, copy number 5–6 (within-gene range 4–6): AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1, TOMM40P3, AC034232.1, ADAMTS12, RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1.
- chr5:38,460,925–39,274,528, 13 genes, copy number 5–6 (within-gene range 4–6): AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1.
- chr5:40,512,333–40,755,963, 1 gene, copy number 6 (within-gene range 4–6): TTC33.
- chr5:40,759,379–41,941,743, 18 genes, copy number 6: PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4.
- chr9:12,134–89,850, 7 genes, copy number 6: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr11:85,628,573–86,284,668, 17 genes, copy number 5: TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1.
- chr11:88,113,251–88,409,223, 5 genes, copy number 5 (within-gene range 3–5): RAB38, AP001642.1, MIR3166, CTSC, GAPDHP70.
- chr11:95,756,959–96,389,956, 10 genes, copy number 5: AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82.
- chr11:128,095,758–128,813,267, 8 genes, copy number 5: LINC02725, LINC02098, ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR.
- chr14:24,036,453–24,442,905, 50 genes, copy number 5: DHRS4L1, CARMIL3, CPNE6, NRL, PCK2, DCAF11, AL136295.3, FITM1, PSME1, EMC9, AL136295.2, PSME2, MIR7703, RNF31, AL136295.5, RNA5SP383, IRF9, REC8, IPO4, AL136295.4, AL136295.22, TM9SF1, AL136295.1, AL136295.6, AL136295.7, TSSK4, CHMP4A, AL096870.2, MDP1, NEDD8-MDP1, NEDD8, GMPR2, TINF2, TGM1, RABGGTA, AL096870.12, AL096870.10, DHRS1, NOP9, CIDEB, LTB4R2, LTB4R, ADCY4, AL096870.1, RIPK3, NFATC4, NYNRIN, CBLN3, KHNYN, SDR39U1.
- chr14:30,370,108–31,207,804, 21 genes, copy number 5: AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P.
- chr14:34,981,957–35,029,686, 1 gene, copy number 11 (within-gene range 3–11): SRP54.
- chr14:49,570,984–52,952,864, 112 genes, copy number 6 (broad region; genes not listed).
- chr14:61,529,128–61,796,428, 9 genes, copy number 7 (within-gene range 4–7): AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1, SNAPC1.
- chr19:28,294,093–30,228,715, 43 genes, copy number 7–17 (within-gene range 1–17): AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1.
- chr19:36,797,502–36,916,291, 6 genes, copy number 9: ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61.
- chr19:44,392,439–44,931,386, 29 genes, copy number 7–11 (within-gene range 2–11): AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1.

Autosomal genes at a single copy (total copy number 1): 6,413. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
